Somatic mutation profile of tumor specimen 0DHE07 from CCDI case PBBTXH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.0 years (1,107 days).
Specimen 0DHE07: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 330dd771-5b8f-4a58-94c5-fb71c321bba9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHDZF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ba56a1a-e292-4378-80d8-105766bb68bc

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C14orf39 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549495863, COSV58786050; called by muse, varscan2
- LIG1 | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 284/664 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754908493; called by muse, varscan2
- ROBO4 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 276/556 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs1002524568; called by muse, varscan2
- SHANK2 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 270/590 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.176); catalogued as rs199629765, COSV53588648; called by muse, varscan2
- PEAK1 | c.4782G>T p.Q1594H | Missense Mutation (SNP) | VAF 156/334 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- USH1C | c.1015_1016del p.R339Afs*15 | Frame Shift Del (DEL) | VAF 138/385 reads (36%) | called by pindel, varscan2
- COL22A1 | c.4797C>T p.P1599= | Silent (SNP) | VAF 208/412 reads (50%) | catalogued as rs776786087, COSV100278072; called by muse, varscan2
- SLC30A9 | c.54G>A p.L18= | Silent (SNP) | VAF 204/440 reads (46%) | called by muse, varscan2
- EPN1 | c.-101-1399G>A | Intron (SNP) | VAF 68/135 reads (50%) | catalogued as rs1234811453; called by muse, varscan2
